TCGA case TCGA-37-A5EL — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aecd6689-f203-4519-afab-3f46ee9d3e2c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 53 years; Vital status: Dead; Days to death: 1,143 days (3.1 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 53.0 years (19,371 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,143 days (3.1 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 215 days; Days to treatment end: 222 days; Treatment dose: 35 Gy; Treatment outcome: Partial Response; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 222 days; Days to treatment end: 228 days; Treatment outcome: Partial Response.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 55.6 years (20,317 days); Days to diagnosis: 946 days (2.6 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Days to follow up: 454 days (1.2 years); Disease response: Tumor Free.
- Day 946 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 946 days (2.6 years).
- Days to follow up: 1,143 days (3.1 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-37-A5EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-37-A5EL-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-37-A5EL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-37-A5EL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Central Lung; Pulmonary function test indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Temodal.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,143 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,143 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 946 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-37-A5EL-01A-11D-A26L-01): tumor purity 0.77, ploidy 3.68, whole-genome doublings 1.
